Somatic mutation profile of tumor specimen TCGA-V4-A9F0-01A (aliquot TCGA-V4-A9F0-01A-11D-A39W-08) from TCGA case TCGA-V4-A9F0, project TCGA-UVM (Uveal Melanoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Mixed epithelioid and spindle cell melanoma; Tissue or organ of origin: Ciliary body; AJCC pathologic stage: Stage IIIB; Age at diagnosis: 59.3 years (21,675 days).
Specimen TCGA-V4-A9F0-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) e38b44ed-3309-45b9-8556-11ce2b6b47b5.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-V4-A9F0-10A (Blood Derived Normal), aliquot TCGA-V4-A9F0-10A-01D-A39Z-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/a6c5c228-1ba0-4978-82ea-c5b281ef1e1c

The open-access MAF lists 8 somatic variants for this specimen: 7 protein-altering or splice-affecting, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 5, Frame Shift Del 1, Frame Shift Ins 1, Intron 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- GNAQ | c.626A>T p.Q209L | Missense Mutation (SNP) | VAF 42/91 reads (46%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs121913492, COSV54105903, COSV54105914, COSV54108414; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- BAP1 | c.1366del p.Q456Rfs*115 | Frame Shift Del (DEL) | VAF 12/21 reads (57%) | catalogued as COSV56240393, COSV99964331; called by pindel, varscan2
- GNB1 | c.964G>C p.D322H | Missense Mutation (SNP) | VAF 14/44 reads (32%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.686); catalogued as COSV66100547; called by muse, mutect2, varscan2
- KCNV1 | c.732C>G p.I244M | Missense Mutation (SNP) | VAF 24/78 reads (31%) | SIFT tolerated (0.31); PolyPhen benign (0.291); called by muse, mutect2, varscan2
- TNIP1 | c.1840G>C p.V614L | Missense Mutation (SNP) | VAF 17/33 reads (52%) | SIFT tolerated, low confidence (0.06); PolyPhen possibly damaging (0.574); called by muse, mutect2, varscan2
- TRIM67 | c.1028T>C p.M343T | Missense Mutation (SNP) | VAF 3/12 reads (25%) | SIFT tolerated (0.2); PolyPhen benign (0.046); called by muse, mutect2
- TYRP1 | c.1165_1166dup p.Q390Dfs*27 | Frame Shift Ins (INS) | VAF 19/93 reads (20%) | called by mutect2, pindel, varscan2
- PITPNM2 | c.2404+702G>A | Intron (SNP) | VAF 8/21 reads (38%) | catalogued as COSV54902835; called by muse, mutect2, varscan2
